CPTAC case C3N-04691 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/65835e17-0795-4ee9-88ee-cf4961244905

Demographics
Sex at birth: male; Race: white; Year of birth: 1957; Vital status: Dead; Days to death: 257 days; Year of death: 2019; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Parietal lobe; Age at diagnosis: 61.4 years (22,433 days); Year of diagnosis: 2018; Days to last known disease status: 257 days; Days to last follow up: 257 days.
   Pathology details: Greatest tumor dimension: 6 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 257.

Other clinical attributes
- Weight: 88 kg; Height: 183 cm; BMI: 26.28.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04691-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 349 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04691-21: Section location: Parietal Lobe; Percent tumor nuclei: 60; Percent necrosis: 10.
- Sample C3N-04691-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
